CCDI case PBCHIC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/291f3829-340a-4e13-a827-022c37e18d2f

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 11.0 years (4,025 days).

Biospecimens (3 samples)
- Sample 0DRZIL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRZIY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRZJH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
